Somatic mutation profile of tumor specimen 0DFMID from CCDI case PBBRYJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 10.3 years (3,772 days).
Specimen 0DFMID: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd6a7343-963b-4ac3-b997-0ed1d73a3df4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMIE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c830038-2dd3-4d07-afea-b1d75fea36b8

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1B | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); catalogued as rs782107041; called by muse, varscan2
- MFF | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 177/968 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs758278774; called by muse, varscan2
- TIMP2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 132/727 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1344433839; called by muse, varscan2
- TLR1 | c.1898G>T p.R633I | Missense Mutation (SNP) | VAF 147/877 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs769128800; called by muse, varscan2
- ARHGAP11A | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 131/652 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CIP2A | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 88/458 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, varscan2
- DDX60 | c.2572C>A p.Q858K | Missense Mutation (SNP) | VAF 82/560 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KLHL25 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, varscan2
- STK4 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 118/929 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, varscan2
- TNRC6B | c.5315T>C p.L1772P (on ENST00000454349 / NM_001162501.2; = p.L1662P on NM_015088.3) | Missense Mutation (SNP) | VAF 176/948 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- CDHR1 | c.1032G>T p.V344= | Silent (SNP) | VAF 116/622 reads (19%) | called by muse, varscan2
- FBXL12 | c.325C>T p.L109= | Silent (SNP) | VAF 75/209 reads (36%) | catalogued as rs1240541910; called by muse, varscan2
- ZNF273 | c.240C>G p.V80= | Silent (SNP) | VAF 188/525 reads (36%) | catalogued as rs1224514925; called by muse, varscan2
- GPAT2 | c.1357+23C>G | Intron (SNP) | VAF 102/252 reads (40%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- OOEP | chr6:73369892 C>A | 5'Flank (SNP) | VAF 6/47 reads (13%) | called by muse, varscan2
- ZFP36L1 | c.-106C>T | 5'UTR (SNP) | VAF 259/682 reads (38%) | catalogued as rs1283864235, COSV100322546; called by muse, varscan2
